Somatic mutation profile of tumor specimen TARGET-10-PATLHS-09A (aliquot TARGET-10-PATLHS-09A-01D) from TARGET case TARGET-10-PATLHS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.0 years (4,004 days).
Specimen TARGET-10-PATLHS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5e1fde5-a2b5-42d9-8a8a-65d823b18e97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLHS-10A (Blood Derived Normal), aliquot TARGET-10-PATLHS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa3a8ee4-1784-4f71-a58e-1becc9cf427e

The open-access MAF lists 31 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 8, 5'UTR 3, Intron 3, Nonsense Mutation 2, Splice Site 1, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA12 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs763409391, COSV51604145; called by muse, mutect2, varscan2
- CEBPB | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV57276752; called by muse, mutect2, varscan2
- CETP | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52361502; called by muse, mutect2, varscan2
- CYP11B1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1455151513, COSV52824869; called by muse, mutect2, varscan2
- JADE2 | c.59-1G>A p.X20_splice | Splice Site (SNP) | VAF 44/49 reads (90%) | catalogued as COSV50911728; called by muse, mutect2, varscan2
- JAK3 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV71685563, COSV71686026; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2
- MAP1A | c.1396_1401del p.P466_F467del | In Frame Del (DEL) | VAF 6/74 reads (8%) | catalogued as rs1214184845, COSV55806149; called by mutect2, pindel*
- NOTCH1 | c.4582T>C p.C1528R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53029190; called by muse, mutect2, varscan2
- PCDHGC5 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs771124496, COSV52743399; called by muse, mutect2, varscan2
- PHACTR2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV59850355; called by muse, mutect2, varscan2
- SMURF2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV52312746, COSV52314115; called by muse, mutect2, varscan2
- NOTCH1 | c.7351_7355dup p.V2453Wfs*26 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- OASL | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- PHF6 | c.138+1del | Frame Shift Del (DEL) | VAF 41/58 reads (71%) | called by mutect2, pindel, varscan2
- CCL22 | c.186G>A p.R62= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- DAB2IP | c.561A>G p.A187= (on ENST00000408936; = p.A159= on NM_032552.3) | Silent (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- DKK1 | c.264C>T p.D88= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1457993160, COSV100906486; called by muse, mutect2, varscan2
- FLG2 | c.1326C>T p.F442= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as rs770065658, COSV66174538; called by muse, mutect2, varscan2
- KMT2C | c.9459C>T p.G3153= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- NPHS1 | c.2634C>T p.N878= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs746676515; called by muse, mutect2, varscan2
- PDZD2 | c.504C>T p.G168= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs375900576; called by muse, mutect2, varscan2
- SCART1 | c.2878C>T p.L960= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- COMP | c.-10C>T | 5'UTR (SNP) | VAF 13/23 reads (57%) | catalogued as rs1449006133; called by muse, mutect2, varscan2
- EIF3L | c.34-147T>A | Intron (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- PMM2 | c.178+314_178+315delinsT | Intron (DEL) | VAF 7/44 reads (16%) | called by pindel, varscan2*
- PRMT8 | c.418-157del | Intron (DEL) | VAF 6/12 reads (50%) | catalogued as rs1211079790; called by mutect2, varscan2
- SULF1 | c.*684C>A | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- TMEM200C | chr18:5890153 G>A | 3'Flank (SNP) | VAF 48/89 reads (54%) | called by muse, mutect2, varscan2
- TRPC7 | c.-61G>A | 5'UTR (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- ZNF638 | c.-178C>T | 5'UTR (SNP) | VAF 43/95 reads (45%) | catalogued as rs1329873404, COSV100038995; called by muse, mutect2, varscan2
